Somatic mutation profile of tumor specimen TCGA-DD-A3A4-01A (aliquot TCGA-DD-A3A4-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 37.6 years (13,739 days).
Specimen TCGA-DD-A3A4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd406ca7-d811-4774-8b39-b30fa3dfafac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A4-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A4-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e49d31a-0480-4104-bd08-83ddefb7d92d

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 61/132 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATG16L1 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV61467216; called by muse, mutect2, varscan2
- C1orf94 | c.1446+1G>T p.X482_splice (on ENST00000488417 / NM_001134734.2; = p.X292_splice on NM_032884.5) | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as rs754997639, COSV64914974; called by muse, mutect2, varscan2
- CMYA5 | c.10520C>A p.S3507Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV71408439; called by muse, mutect2, varscan2
- CRACDL | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV67409579; called by muse, mutect2, varscan2
- CUX2 | c.1186C>A p.L396I | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV55642655; called by muse, mutect2, varscan2
- DTX3 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54089516; called by muse, mutect2, varscan2
- EIF2B5 | c.506+2T>A p.X169_splice | Splice Site (SNP) | VAF 44/112 reads (39%) | catalogued as COSV56605726; called by muse, mutect2, varscan2
- ELOVL7 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV70917614; called by muse, mutect2, varscan2
- ITGA4 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1195462762, COSV52002814; called by muse, mutect2, varscan2
- ITGB8 | c.525A>T p.R175S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV56012326; called by muse, mutect2, varscan2
- KIFAP3 | c.380A>T p.D127V | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV63036036; called by muse, mutect2, varscan2
- MACROH2A2 | c.10del p.R4Gfs*25 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | catalogued as COSV64713814; called by mutect2, pindel, varscan2
- PALD1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1022510891, COSV54977237; called by muse, mutect2, varscan2
- PGBD2 | c.857G>T p.R286M | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV61400792; called by muse, mutect2, varscan2
- PHF8 | c.518T>G p.L173R (on ENST00000357988 / NM_001184896.1; = p.L137R on NM_015107.3) | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57685955; called by muse, mutect2, varscan2
- PHKB | c.1300T>A p.C434S | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54530261; called by muse, mutect2, varscan2
- PSIP1 | c.149+1G>T p.X50_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV66255392, COSV66255775; called by muse, mutect2, varscan2
- PXDNL | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.389); catalogued as rs757076660, COSV62480016; called by muse, mutect2, varscan2
- RGL1 | c.1939G>T p.E647* (on ENST00000360851 / NM_001297672.2; = p.E682* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV58992354; called by muse, mutect2, varscan2
- RGS22 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100692922, COSV62665595; called by muse, mutect2, varscan2
- TCF20 | c.2732C>G p.P911R | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1400044584, COSV100166204, COSV59494704; called by muse, mutect2, varscan2
- TMEM132E | c.1363G>C p.D455H (on ENST00000321639; = p.D545H on NM_001304438.2) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV58699477; called by muse, mutect2, varscan2
- ZNF415 | c.983A>T p.Y328F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV54703737; called by muse, mutect2
- ZNF862 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56225360; called by muse, mutect2, varscan2
- ZNF862 | c.1470C>A p.C490* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV56225369; called by muse, mutect2, varscan2
- ZSCAN29 | c.1447A>C p.T483P | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV67823086; called by muse, mutect2, varscan2
- GPAM | c.2431_2434del p.P811Nfs*8 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- RELCH | c.3090_3114+8del p.X1030_splice | Splice Site (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- CSMD1 | c.7911G>A p.T2637= (on ENST00000520002; = p.T2636= on NM_033225.6) | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs374916113, COSV59300184, COSV59301955; called by muse, mutect2, varscan2
- DNAH11 | c.4125C>T p.R1375= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs570983771, COSV100180953, COSV60972118; called by muse, mutect2, varscan2
- GGN | c.162C>T p.S54= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53056033; called by muse, mutect2
- GUSB | c.1413A>G p.K471= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59223105; called by muse, mutect2, varscan2
- IGHV2-70 | c.327G>T p.V109= | Silent (SNP) | VAF 117/315 reads (37%) | catalogued as rs554810270; called by muse, mutect2, varscan2
- MITF | c.1431C>A p.I477= (on ENST00000448226 / NM_006722.3; = p.I377= on NM_000248.4) | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV58834503; called by muse, mutect2, varscan2
- ST8SIA2 | c.810C>T p.Y270= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV51571832; called by muse, mutect2, varscan2
- UXT | c.255T>C p.D85= | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as COSV60039882; called by muse, mutect2, varscan2
